Surgical pathology report (de-identified scan), TCGA case TCGA-67-3771, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site St Joseph's Medical Center (MD), specimen TCGA-67-3771-01A (Primary Tumor).

[page 1 of 5]
PRIORITY: FROZEN SEC

SURGICAL PROCEDURES:

LUNG-LOBECTOMY, REGIONAL LYMPH

CLINICAL HISTORY

PERTINENT CLINICAL HISTORY: LEFT LUNG CA.

GROSS DESCRIPTION

A. The specimen is submitted fresh for frozen section as "level 5" and consists of a red black 1.9 cm nodule; bisected and submitted in toto, 2 (1) labeled "FSP" for frozen section. A touch prep has been taken.

FROZEN SECTION DIAGNOSIS: Node negative for tumor. [REDACTED]

B. The specimen is submitted fresh for frozen section as "level 6" and consists of two black nodular segments measuring 0.6 cm and 1.8 cm in dimension; each is bisected and submitted in toto 4 (1) labeled "FSP" for frozen section. A touch prep has been taken.

FROZEN SECTION DIAGNOSIS: Nodes negative for tumor. [REDACTED]

C. The specimen is submitted fresh for frozen section as "level 9L" and consists of a pink red 1.1 cm nodule; bisected and submitted in toto, 2 (1) and labeled "FSP" for frozen section. A touch prep has been taken.

FROZEN SECTION DIAGNOSIS: Nodes negative for tumor. [REDACTED]

D. The specimen is submitted fresh for TCGA study as "left upper lobe (time of resection 12:01)" and consists of a lobe of lung weighing 162 grams and measuring 23 x 9 x 2 cm. The pleural surface is deep red purple and reticulated by carbon pigment with a firm puckered 2 x 2 cm area along the lateral apex. There is an adjacent 2 x 2 cm roughened focally hemorrhagic area. The hilum exhibits a 4.5 cm staple line. Removal of the staple line reveals two segments of bronchi measuring approximate 1 cm

[page 2 of 5]
GROSS DESCRIPTION

(Continued)

each in diameter and four vessel margins varying 0.3 cm to 0.5 cm in diameter. Several grey black friable nodules are clustered about the hilum. Sectioning reveals a 2.5 x 2.5 x 1.8 cm yellow tan tumor which appears to abut the puckered area of the pleura previously described and is 4 cm from bronchial margin. The adjacent roughening corresponds to the diffusely thickened pleura measuring up to 0.3 cm in maximum thickness. The pulmonary parenchyma distal to the tumor is deep red and honeycombed. The remaining pulmonary parenchyma is deep red and airless. Representative sections are submitted, multiple (9):

Cassette 1:	Bronchial margin
Cassette 2:	Vessel margin
Cassette 3:	Nodules clustered about the hilum
Cassettes 4 - 6:	Tumor (pleural surface; black)
Cassette 7:	Thickened pleural area
Cassette 8:	Representative pulmonary parenchyma distal to the tumor
Cassette 9:	Representative uninvolved pulmonary parenchyma

Please note: A tumor sample is collected and submitted for TCGA studies.

E. The specimen is submitted fresh as "anterior hilar node" and consists of a soft red black tissue fragment measuring 1.5 x 1 x 0.3 cm. The specimen is submitted in toto, 1 (1).

F. The specimen is submitted fresh as "posterior hilar node" and consists of a soft red black tissue fragment measuring 1.3 x 1 x 0.3 cm. The specimen is wrapped in tissue paper and submitted in toto, 1 (1).

G. The specimen is submitted fresh as "lobar node" and consists of a soft red black tissue fragment measuring 0.6 x 0.5 x 0.2 cm. The specimen is wrapped in tissue paper and submitted in toto, 1 (1).

H. The specimen is submitted fresh as "interlobar node (sump)" and consists of three red black tissue fragments ranging 0.6 to 0.8 cm in dimension. The specimen is wrapped in tissue paper and submitted in toto, 3 (1).

I. The specimen is submitted fresh as "lingular node" and consists of two soft friable red black tissue fragments measuring 0.6 and 0.8 cm in dimension. The specimen is wrapped in tissue paper and submitted in toto, 2 (1).

[page 3 of 5]
FINAL DIAGNOSIS

- A. LYMPH NODE, LEVEL 9:
- LYMPH NODE, NEGATIVE FOR TUMOR.
- B. LYMPH NODE, LEVEL 6:
- TWO LYMPH NODES, NEGATIVE FOR TUMOR.
- C. LYMPH NODE, LEVEL 9:
- LYMPH NODE, NEGATIVE FOR TUMOR.
- D. LUNG, LEFT UPPER LOBE, LOBECTOMY:
- ADENOCARCINOMA. SEE SYNOPTIC REPORT.
- E. LYMPH NODE, ANTERIOR HILAR:
- LYMPH NODE, NEGATIVE FOR TUMOR.
- F. LYMPH NODE, POSTERIOR HILAR:
- LYMPH NODE, NEGATIVE FOR TUMOR.
- G. LYMPH NODE, LOBAR:
- LYMPH NODE, NEGATIVE FOR TUMOR.
- H. LYMPH NODE, INTRALOBAR (SUMP):
- LYMPH NODE FRAGMENTS X 3, NEGATIVE FOR TUMOR.
- I. LYMPH NODE, LINGULAR:
- FRAGMENTS OF LYMPH NODES, NEGATIVE FOR TUMOR.

[page 4 of 5]
SYNOPTIC REPORT

(Continued)

TUMOR SITE: LEFT UPPER LOBE
TUMOR SIZE: 2.5 CM
HISTOLOGIC TYPE: ADENOCARCINOMA
HISTOLOGIC GRADE: 2-3 (MODERATELY TO POORLY DIFFERENTIATED)
EXTENT OF INVASION: CONFINED TO LUNG
EXTENSION TO PLEURA/OTHER STRUCTURES (SPECIFY): NONE IDENTIFIED
ADDITIONAL PERTINENT FINDINGS - NO ATELECTASIS OR PNEUMONIA IDENTIFIED

MARGINS:

BRONCHIAL: UNINVOLVED
PARENCHYMAL: UNINVOLVED
VASCULAR: UNINVOLVED
DISTANCE TO PERTINENT MARGIN(S): 4 CM TO BRONCHIAL MARGIN

VENOUS INVASION: ABSENT
ARTERIAL (LARGE VESSEL) INVASION: ABSENT

LYMPH NODE:

f, , , , N1 - # INVOLVED/# EXAMINED: 0/5+
f, , , , N2 - # INVOLVED/#EXAMINED: 0/8+
f, , , , N3 - # INVOLVED/# EXAMINED: 0/0

OTHER PERTINENT FINDINGS:

- NO VISCERAL PLEURAL INVASION IDENTIFIED.

PTNM STAGE: pT1 N0

[page 5 of 5]
GROSS DESCRIPTION

RECEIVED: Slide 32.5 cc Fluid* X Fresh Fixed Type Fix

* Volume may reflect total of specimen, fixative, and/or collection fluid.

APPEARANCE: X Clear Cloudy Foamy Bloody

Clotted Tissue Color COLORLESS

PREP: 6 Smear(s) Diff Quick(s) Filter(s) 2 Cell Block(s)

Cytospin(s) - 2 Singles(s) Double(s)

H&E Unstained

Comment:

FINAL DIAGNOSIS

LEFT UPPER LUNG, LEFT UPPER LOBE (FINE NEEDLE ASPIRATION BIOPSY):

- POSITIVE FOR MALIGNANT CELLS.
- NON SMALL CELL CARCINOMA WITH FEATURES OF ADENOCARCINOMA OF THE LUNG.
- IMMUNOHISTOCHEMISTRY FOR CYTOKERATIN 7 IS POSITIVE, AND CK20, CK5/6, AND P63 ARE NEGATIVE. TTF-1 IS ALSO NEGATIVE, AND RESULTS OF REPEAT TTF-1 WILL BE ISSUED AS AN ADDENDUM.

INTRADEPARTMENTAL CONSULTATION:

Source: NCI Genomic Data Commons file 619d40a4-fe44-4e0a-bcc3-e4ae939ff26f (TCGA-67-3771.4BCFC5F3-136C-46B5-8E90-6BE1ABE3A9D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).